Somatic mutation profile of tumor specimen MP2PRT-PAUAHK-TMP1-A (aliquot MP2PRT-PAUAHK-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUAHK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,740 days).
Specimen MP2PRT-PAUAHK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ee1f409-63d8-4263-af5d-acb50f229974.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUAHK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUAHK-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6346d5c7-c68f-413a-b2a5-263178d24289

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 30/232 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/290 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACSM6 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 68/424 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58980875; called by muse, mutect2
- CHTF18 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 167/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs749093068, COSV99136042; called by muse, mutect2, varscan2
- DPP10 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1244491850, COSV59716204; called by muse, mutect2, varscan2
- FMN2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 200/445 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); catalogued as rs773926457, COSV100146740; called by muse, mutect2, varscan2
- GRIK2 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 112/234 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs188057768, COSV59710460; called by muse, mutect2, varscan2
- HMGN2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs924440366; called by muse, mutect2
- PTGFRN | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 165/342 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760138046, COSV104432156; called by muse, mutect2, varscan2
- RYR2 | c.12313C>A p.L4105I | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1413565928, CM097969, COSV100769319; called by muse, mutect2, varscan2
- TDO2 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 114/263 reads (43%) | catalogued as rs530115805; called by muse, mutect2, varscan2
- TENM4 | c.6239G>A p.R2080H | Missense Mutation (SNP) | VAF 173/353 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs935968915, COSV53643597; called by muse, mutect2, varscan2
- TESK1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 203/473 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs142090865; called by muse, mutect2, varscan2
- XKR7 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 201/448 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530229497, COSV73813066; called by muse, mutect2, varscan2
- CYTH2 | c.354-1G>A p.X118_splice | Splice Site (SNP) | VAF 81/169 reads (48%) | called by muse, mutect2, varscan2
- DCST2 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGCR | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- IGKJ2 | c.1_16delinsGGGCAAG p.C2_Q6delinsAR | In Frame Del (DEL) | VAF 90/106 reads (85%) | called by pindel, varscan2*
- OR51L1 | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF17 | c.735T>A p.D245E | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRCP | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SERPINI1 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCLAF1 | c.51A>G p.S17= | Silent (SNP) | VAF 91/199 reads (46%) | called by muse, mutect2, varscan2
- CBLL2 | c.1266T>C p.H422= | Silent (SNP) | VAF 138/145 reads (95%) | called by muse, mutect2, varscan2
- DST | c.5820A>G p.G1940= | Silent (SNP) | VAF 116/290 reads (40%) | called by muse, mutect2, varscan2
- LRRTM1 | c.696C>T p.L232= | Silent (SNP) | VAF 31/415 reads (7%) | catalogued as COSV54440438; called by muse, mutect2
- MAPK8IP1 | c.873C>T p.D291= | Silent (SNP) | VAF 217/484 reads (45%) | catalogued as rs138625751; called by muse, mutect2, varscan2
- PCDHB12 | c.1353C>T p.F451= | Silent (SNP) | VAF 110/554 reads (20%) | called by muse, mutect2, varscan2
